Surgical pathology report (de-identified scan), TCGA case TCGA-DA-A3F8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Yale, specimen TCGA-DA-A3F8-06A (Metastatic).

[page 1 of 3]
REPORT

Patient: [REDACTED]
MR #: [REDACTED]
DOB/Age/Sex: [REDACTED] Age: M
YNHH Visit #: [REDACTED]
Submitting Physician: [REDACTED]

Accession #: [REDACTED]
Taken: [REDACTED]
Accessioned: [REDACTED]
Adm-Disch Date: [REDACTED]
Reported: [REDACTED]

Clinical History and Impression:
year-old male with melanoma.

Specimen(s) Received:
1: LEFT CERVICAL LYMPH NODE
2: WIDE EXCISION LEFT MELANOMA
3: LEVEL 2B LYMPH NODE
4: LEVEL 4 AND 5 LYMPH NODE
5: LEVEL 2A AND 3 LYMPH NODE

FINAL DIAGNOSIS

1. LEFT CERVICAL LYMPH NODE, EXCISION:
- METASTATIC MELANOMA (2.5 CM)
INVOLVING ONE LYMPH NODE (1/1)
- NO EXTRACAPSULAR EXTENSION SEEN
2. LESION, LEFT NECK, WIDE EXCISION:
- SKIN AND SUBCUTANEOUS TISSUE WITH SCAR
- NO RESIDUAL MELANOMA SEEN
(SEE NOTE)
3. LEVEL 2B LYMPH NODES, EXCISION:
- TWENTY-TWO LYMPH NODES, NEGATIVE FOR TUMOR (0/22)
4. LEVEL 4 AND 5 LYMPH NODES, EXCISION:
- METASTATIC MELANOMA (0.8 CM)
INVOLVING ONE OF TWENTY-TWO LYMPH NODES (1/22)
- NO EXTRACAPSULAR EXTENSION SEEN
5. LEVEL 2A AND 3 LYMPH NODES, EXCISION:
- FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4)

Page 1 of 3

Pathologic Complete Response		X
Qual/Synchronous Primary	Noted	
Reviewed/Initiated	[Signature] 11/13/11	

ICD-0-3

Melanoma, NOS 8720/3

Site: lymph node, cervical C77.0

lw 11/13/11

[page 2 of 3]
NOTE: Part 2 has been reviewed by the
Based on the previous biopsy [REDACTED] and current specimen, the tumor would be staged as: pT2a, N2b; at least Stage IIIB (AJCC 7th ed).

Pathologist: [REDACTED]

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

1. Received fresh in the frozen section laboratory, labeled with the patient's name, unit number and "left cervical lymph node," is a 2.8 x 2.2 x 1.4 cm half of a tan rubbery lymph node. A representative section is frozen as FSA, now in cassette 1. The remaining tissue is entirely submitted in cassettes 2-4.
2. Received fresh labeled with the patient's name and "wide excision left melanoma," a 5.5 x 2.3 cm tan-pink, hair bearing skin ellipse excised to a depth of 0.9 cm. The specimen is oriented with a stitch designating superior. The epidermis displays a centrally located, 0.8 x 0.7 cm pink, ill-defined area, 0.7 cm in nearest margin. The specimen is inked as follows: Anterior-blue, posterior-green. The specimen is serially sectioned from superior to inferior and sequentially submitted in 12 cassettes with cassettes 2-9 to include the pink area.
3. Received fresh labeled with the patient's name and "level IIB lymph node," is a 7.5 x 6.0 x 1.3 cm aggregate of fibrofatty tissue. Sectioning reveals 21 possible rubbery, tan-pink to yellow lymph nodes ranging from 0.2 to 2.0 cm in greatest dimension. The lymph nodes are entirely submitted in 6 cassettes as follows: cassette 1- 6 possible lymph nodes, cassette 2- 5 possible lymph nodes, cassette 3- 5 possible lymph nodes, cassette 4- 3 possible lymph nodes, cassette 5-one lymph node bisected, cassette 6-one lymph node bisected.
4. Received fresh labeled with the patient's name and "level IV and 5 lymph nodes" is a 13.0 x 5.5 x 1.5 cm portion of fibrofatty tissue which is focally cauterized. There is no attached to the muscle or vasculature. Sectioning reveals 23 possible rubbery, tan-pink to yellow lymph nodes ranging from 0.3-1.8 cm in greatest dimension. The lymph nodes are entirely submitted in 10 cassettes as follows: Cassette 1-5 possible lymph nodes, cassette 2-5 possible lymph nodes, cassette 3-3 possible lymph nodes, cassette 4-2 possible lymph nodes, cassette 5-2 possible lymph nodes, cassette 6-2 possible lymph nodes, cassette 7-one lymph node bisected, cassette 8-one lymph node bisected, cassette 9-one lymph node bisected, cassette 10-one lymph node bisected.
5. Received fresh labeled with the patient's name and "level IIA and 3 lymph nodes," is a 4.5 x 3.0 x 0.8 cm portion of fibrofatty tissue. Sectioning reveals 4 rubbery, tan-pink possible lymph nodes ranging from 0.5-1.8 cm. The lymph nodes are entirely submitted in 3 cassettes as follows: Cassette 1-2 lymph nodes, cassette 2-one lymph node bisected, cassette 3-one lymph node bisected.

Frozen/Intraoperative Diagnosis:

Left Cervical Lymph Node: Metastatic melanoma involving one lymph node [1 block]

Summary of Stains Performed and Reviewed
H&E, Recut, Level

Count
20

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] LEFT CERVICAL LYMPH NODE	4	[Undes]	(3)	(No Description)
		FSA	(1)	(No Description)
Part 2] WIDE EXCISION LEFT MELANOMA	12	[Undes]	(4)	(No Description)
		[Undes]	(1)	Inferior Tip
		[Undes]	(6)	Lesion
		[Undes]	(1)	Superior Tip

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Part 3] LEVEL 2B LYMPH NODE	6	MLN	(4)	Multiple LN's (each own node)
		SLN	(2)	Single Lymph Node (all 1 node)
Part 4] LEVEL 4 AND 5 LYMPH NODE	10	MLN	(6)	Multiple LN's (each own node)
		SLN	(4)	Single Lymph Node (all 1 node)
Part 5] LEVEL 2A AND 3 LYMPH NODE	3	MLN	(1)	Multiple LN's (each own node)
		SLN	(2)	Single Lymph Node (all 1 node)
Total:	35			

END OF REPORT

Page 3 of 3

Source: NCI Genomic Data Commons file 475a4549-1bb7-4acd-a6ef-06f5cbaa6eef (TCGA-DA-A3F8.7FA3301F-4D8C-4785-BC7A-83A5C8080C46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).